Surgical pathology report (de-identified scan), TCGA case TCGA-AA-3543, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-3543-01A (Primary Tumor).

Diagnosis:

Right hemicolectomy preparation with an ulcerated colon carcinoma of the histological type of a moderately differentiated, partially mucus-producing, colorectal adenocarcinoma, almost completely enveloping the blind intestine, measuring 4cm in diameter at the widest point. Invasive spreading of tumor to the outer edges of the muscularis propria. Colon mucous membrane with a small tubular adenoma with moderate epithelial dysplasia (synonymously: mild intraepithelial neoplasia). Appendix with mild fibrosis of the wall.

Tumor-free oral and aboral resection border as well as greater omentum.

Twenty five mesocolic and mesenteric lymph nodes tumor-free with uncharacteristically reactive changes.

Tumor stage therefore pT2 pN0 (0/25) L0 V0; G2 R0.

Source: NCI Genomic Data Commons file 4150a171-16a6-4df2-8cb2-32164284fff4 (TCGA-AA-3543.978056B3-EBF5-465A-AC1D-F470890298A7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).